Surgical pathology report (de-identified scan), TCGA case TCGA-YZ-A980, project TCGA-UVM (Uveal Melanoma), tissue source site The Ohio State University, specimen TCGA-YZ-A980-01A (Primary Tumor).

[page 1 of 4]
Facility

Name

Result Information

Status

Final result

Provider Status

Ordered

Observation Date and Time

Entry Date

Component Results

Component

SPECIMEN DESCRIPTION

(NOTE)

Surgical Pathology Report

Patient Name: [REDACTED]

Accession #: [REDACTED]

Med. Rec #: [REDACTED]

Submitting Physician: [REDACTED]

*****Clinical History*****

Melanoma left eye

ICD-O 3

Melanoma, spindle cell & epithelioid mixed 8770/3

Site Choroid C69.3

path Ocular tract C69.4

JW 3/12/14

*****Final Pathologic Diagnosis*****

- A. Eye, left, enucleation:
- Malignant melanoma, mixed cell type.
- Ciliary body involvement present.
- No extrascleral extension.
- See Synoptic Report.

All controls show appropriate reactivity.

The immunohistochemical and/or in situ hybridization tests reported here, except for those addressing HER-2Neu overexpression, have been developed and their performance characteristics determined by the Immunohistochemistry and

have nor do they have FDA approval.

id are not required to

The above diagnosis is based on my personal examination of the slides and, if indicated, other material relevant to the case. I have reviewed and approved this report prior to its release.

Ophthalmologist

[page 2 of 4]
Electronically Signed By

*****Synoptic Report*****

SYNOPTIC REPORT FOR UVEAL MELANOMA:

Specimen type: E=enucleation

Laterality: L=left

Specimen size (mm):

For Enucleation

Anteroposterior diameter: 22.0

Horizontal diameter: 22.0

Vertical diameter: 24.0

Length of optic nerve: 0.0 (optic nerve cut flush against globe)

Diameter of optic nerve: 4.0

Tumor site: superior anterior (10:00-1:00 o' clock) adjacent to ciliary body

Tumor basal size on transillumination (mm): 15.0x13.0

Tumor size after sectioning (mm):

Base at cut edge: 14.0

Greatest height: 9.0

Tumor location after sectioning:

Distance from posterior margin of tumor base to edge of optic disc (mm): 19.0

Tumor extent (N=no, Y=yes, NA=not applicable):

Involvement of sclera: N

Involvement of vortex vein(s): N

Involvement of optic disc: N

Involvement of vitreous: N

Involvement of choroid: Y

Involvement of ciliary body: Y

Involvement of iris: N

Involvement of lens: N

Involvement of anterior chamber: N

Involvement of extrascleral extension (anterior): N

Involvement of extrascleral extension (posterior): N

Involvement of Angle/Schlemm's canal: N

Involvement of optic nerve: N

Involvement of retina: N

Involvement of cornea: N

Growth pattern: S=solid

Histologic type: M=mixed (90% spindle, 10% epithelioid)

Histologic grade (pGX-3): pG2 mixed cell type

Margins (N=negative, P=positive, NA=not applicable):

Surgical margins: N

[page 3 of 4]
Extrascleral extension: N

Regional lymph nodes (NA=not applicable):

Number examined: 0
Number positive: NA
Number negative: NA

Additional pathologic findings:

Mitotic rate: 6 mitoses per 10 high power fields
Vascular invasion: Not present
Degree of pigmentation: Light
Inflammatory cells: Scattered intratumoral lymphocytes
Retinal detachment: Present
Invasion of Bruch's membrane: Not identified
Hemorrhage: Not present

Immunostains:

Ki-67 marker: 10%

Pathologic staging (pTNM): pT3b pNX

Comments: >

Pathologic Staging Definitions (pTNM):

Primary Tumor (pT)

Ciliary Body and Choroid

pT3b: Tumor size category 3 with ciliary body involvement

Regional Lymph Nodes (pN)

pNX: Regional lymph nodes cannot be assessed

Distant Metastasis (pM)

Not applicable - *No pM reported if distant metastasis is unknown

The above synoptic report complies, in slightly modified form, with the guidelines of the College of American Pathologists Protocols and the AJCC Cancer Staging Manual, 7th edition, 2010, for the reporting of cancer specimens.

*****MICROSCOPIC:*****

A microscopic examination of H&E and PAS stained slides was performed.

*****SPECIMEN(S) RECEIVED:*****

Eye, enucleation

*****GROSS DESCRIPTION:*****

The specimen is received in one properly labeled container with the patient's name and accession number.

A. The specimen is designated "left eye" and consists of a left eye that is 2.2 cm horizontally, 2.4 cm vertically, and 2.2 cm from anterior to posterior. Transillumination of the specimen reveals a tumor that is 1.5 x 1.3 cm in the superior anterior aspect of the globe. The optic nerve is cut flush with the globe. Upon trisecting, the tan-gray rubbery tumor is 1.4 x 1.3 x 0.9 cm. The tumor is present on the superior

[page 4 of 4]
anterior aspect of the globe adjacent to the ciliary body. The tumor is 1.9 cm from the optic nerve stump. No gross extrascleral extension is noted.

Summary of Cassettes: A1-2, two horizontal cross sections including entire tumor

Lab Use Only: Job ID [REDACTED]

Gross description by:

Patient Release Status:

This result is not viewable by the patient.

Patient Care Team

	Relationship	Specialty	Notifications	Start	End
MD	[REDACTED]				
MD	[REDACTED]	Ophthalmology			
	[REDACTED]	Ophthalmology			
	[REDACTED]	Dermatology			
	[REDACTED]	Ophthalmology			
MD	[REDACTED]	Family Medicine			

Procedures with Linked Chargeables

Chargeable	CPT Code
SURG PATH	88305
SURG PATH	88305

Facility

Name

SURG PATH REQUEST (Order

[REDACTED]

Surg Path

Order # : [REDACTED]

Authorizing: [REDACTED]

M.D.

Department:

Date:

Released By: Results Incoming

Patient Demographics

Patient Name	MRN	Sex	DOB	Address	Phone
[REDACTED]	[REDACTED]	Male	[REDACTED]	[REDACTED]	[REDACTED]

Office/Hospital Location

Name

Allergies as of

No Known Allergies

Order Information

Order Date/Time Release Date/Time Start Date/Time End Date/Time

Source: NCI Genomic Data Commons file 7f084c6f-8e5f-440c-a38c-8b201b83b940 (TCGA-YZ-A980.A0ADAAFB-31A4-468A-9543-F4DFCCBCF0DC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).